Somatic mutation profile of tumor specimen TARGET-40-PAMJXS-01A (aliquot TARGET-40-PAMJXS-01A-01D) from TARGET case TARGET-40-PAMJXS, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 11.2 years (4,100 days).
Specimen TARGET-40-PAMJXS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97d0f607-00ec-49e4-a172-266c5c4ce1c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAMJXS-10A (Blood Derived Normal), aliquot TARGET-40-PAMJXS-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69d5fbda-c9be-4e9f-baa1-bfe77f348fe1

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 28/41 reads (68%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD35 | c.448G>A p.D150N | Missense Mutation (SNP) | VAF 20/430 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV62909779; called by muse, mutect2
- KCNC3 | c.1387G>A p.A463T | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164761485; called by muse, mutect2, varscan2
- MACF1 | c.21970C>T p.R7324W (on ENST00000372915; = p.R5369W on NM_012090.5) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | catalogued as rs1199684800, COSV57114409; called by muse, mutect2, varscan2
- RSF1 | c.2888G>C p.R963P | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as COSV57836020; called by muse, mutect2
- AK9 | c.4720C>G p.Q1574E | Missense Mutation (SNP) | VAF 86/1290 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- APBA1 | c.565G>A p.D189N | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.213); called by muse, varscan2
- B3GNT5 | c.370A>G p.N124D | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- CEP41 | c.460G>C p.G154R | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL6A3 | c.2953C>A p.Q985K | Missense Mutation (SNP) | VAF 14/276 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- CPS1 | c.2465G>C p.G822A | Missense Mutation (SNP) | VAF 10/131 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAI4 | c.594A>T p.E198D | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT tolerated (0.57); PolyPhen benign (0.038); called by muse, mutect2
- ESRRG | c.1220A>C p.H407P | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- HECTD4 | c.5199G>C p.Q1733H | Missense Mutation (SNP) | VAF 32/416 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KCNJ1 | c.713A>G p.E238G | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.092); called by muse, mutect2
- KNDC1 | c.1791C>A p.H597Q | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.979); called by muse, mutect2
- LTA | c.523C>A p.L175I | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PRSS55 | c.960G>T p.M320I | Missense Mutation (SNP) | VAF 66/99 reads (67%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDK5RAP3 | c.1200C>T p.T400= | Silent (SNP) | VAF 18/334 reads (5%) | called by muse, mutect2
- CSPG4 | c.1428A>G p.A476= | Silent (SNP) | VAF 71/309 reads (23%) | called by muse, mutect2, varscan2
- NUP160 | c.1962G>A p.V654= | Silent (SNP) | VAF 8/110 reads (7%) | catalogued as COSV101021560; called by muse, mutect2
- SCN10A | c.3579C>T p.F1193= | Silent (SNP) | VAF 15/108 reads (14%) | catalogued as COSV71860411; called by muse, varscan2
- ADAMTSL1 | c.1575-15G>T | Intron (SNP) | VAF 10/44 reads (23%) | called by muse, mutect2, varscan2
- KCNH8 | c.969+29C>T | Intron (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2
